Somatic mutation profile of tumor specimen TCGA-KN-8435-01A (aliquot TCGA-KN-8435-01A-11D-2310-10) from TCGA case TCGA-KN-8435, project TCGA-KICH (Kidney Chromophobe). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 59.9 years (21,891 days).
Specimen TCGA-KN-8435-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d09cc89e-850a-4ada-80c3-5e59729ef85e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KN-8435-11A (Solid Tissue Normal), aliquot TCGA-KN-8435-11A-01D-2311-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a5bcaa1-6a77-40dc-ac74-64d13a4dc654

The open-access MAF lists 21 somatic variants for this specimen: 18 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Frame Shift Del 2, Silent 2, Frame Shift Ins 1, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.2171G>T p.G724V | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV53753982; called by muse, mutect2, varscan2
- COL2A1 | c.1729C>T p.P577S | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.867); catalogued as rs1437402366, COSV61533247; called by muse, mutect2, varscan2
- DAGLB | c.1521T>A p.D507E | Missense Mutation (SNP) | VAF 9/142 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); catalogued as COSV99766092; called by muse, mutect2
- FCRLA | c.128T>C p.L43P (on ENST00000367959; = p.L26P on NM_032738.4) | Missense Mutation (SNP) | VAF 77/89 reads (87%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as rs763133551; called by muse, mutect2, varscan2
- JAKMIP3 | c.1507C>T p.R503W | Missense Mutation (SNP) | VAF 40/43 reads (93%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs374251347; called by muse, mutect2, varscan2
- NECAB3 | c.252del p.H85Ifs*6 | Frame Shift Del (DEL) | VAF 33/85 reads (39%) | catalogued as COSV55775952; called by mutect2, pindel, varscan2
- ABHD10 | c.854C>A p.A285E | Missense Mutation (SNP) | VAF 117/281 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CD109 | c.3578A>C p.E1193A | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT tolerated (0.49); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- CLASP2 | c.739T>A p.S247T | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- EIF5 | c.46T>C p.Y16H | Missense Mutation (SNP) | VAF 95/204 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.604); called by muse, mutect2, varscan2
- HOXA9 | c.563A>G p.K188R | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- ISLR | c.347G>T p.S116I | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.356); called by muse, mutect2
- KIR2DL4 | c.773-1G>C p.X258_splice (on ENST00000396284; = p.X219_splice on NM_001080770.2) | Splice Site (SNP) | VAF 123/327 reads (38%) | called by muse, mutect2, varscan2
- OR6A2 | c.478A>C p.I160L | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- PCNA | c.253G>C p.E85Q | Missense Mutation (SNP) | VAF 96/191 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.358); called by muse, mutect2
- RBM15 | c.676_694del p.E226Sfs*14 | Frame Shift Del (DEL) | VAF 39/64 reads (61%) | called by mutect2, varscan2
- SMARCA5 | c.387dup p.D130Rfs*2 | Frame Shift Ins (INS) | VAF 38/162 reads (23%) | called by mutect2, varscan2
- TMIGD1 | c.173A>G p.N58S | Missense Mutation (SNP) | VAF 105/119 reads (88%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- CPAMD8 | c.3616T>C p.L1206= (on ENST00000651564; = p.L1159= on NM_015692.5) | Silent (SNP) | VAF 162/367 reads (44%) | called by muse, mutect2, varscan2
- WNK2 | c.696C>G p.T232= | Silent (SNP) | VAF 24/51 reads (47%) | called by muse, mutect2, varscan2
- C22orf15 | c.-33A>G | 5'UTR (SNP) | VAF 7/28 reads (25%) | catalogued as COSV100533701; called by muse, mutect2, varscan2
